Somatic mutation profile of tumor specimen TARGET-30-PAMBAC-01A (aliquot TARGET-30-PAMBAC-01A-01W) from TARGET case TARGET-30-PAMBAC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.6 years (945 days).
Specimen TARGET-30-PAMBAC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12921127-ab2c-4b31-b7ea-1e281522a303.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMBAC-14A (Bone Marrow Normal), aliquot TARGET-30-PAMBAC-14A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1fb75c6-a53a-4242-8c13-203be8537f58

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCE | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763151358, COSV57690092; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.9872G>A p.R3291H | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs747787527, COSV51946964; called by muse, mutect2, varscan2
- GPM6B | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 222/241 reads (92%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV57422347, COSV57423826; called by muse, mutect2, varscan2
- OR52N1 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57693858; called by muse, mutect2, varscan2
- QPCTL | c.595C>G p.Q199E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV50004587; called by muse, mutect2
- SLC7A4 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758092768, COSV100298489, COSV60385493; called by muse, mutect2, varscan2
- TMEM273 | c.27G>C p.R9S | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.23); catalogued as COSV65152931, COSV65153803; called by muse, mutect2, varscan2
- AVP | c.42G>A p.L14= | Silent (SNP) | VAF 80/173 reads (46%) | catalogued as COSV66672133; called by muse, mutect2, varscan2
- KRTAP5-8 | c.177C>G p.G59= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as rs541819431, COSV68324812; called by muse, mutect2, varscan2
- OR10H4 | c.831C>T p.A277= | Silent (SNP) | VAF 120/280 reads (43%) | catalogued as COSV59062182, COSV59062585; called by muse, mutect2, varscan2
- PRR14 | c.1263G>A p.G421= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV54913172; called by muse, mutect2, varscan2
